Somatic mutation profile of tumor specimen BA3134D (aliquot aq-BA3134D) from BEATAML1.0 case 2601, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,182 days).
Specimen BA3134D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 043a4c66-9103-4587-8484-325ce5c5357d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3263D (Solid Tissue Normal), aliquot aq-BA3263D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b754722a-56f9-442f-9de7-13a6d92bd1c7

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- C6 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs756691542, COSV54705309; called by muse, mutect2, varscan2
- CELSR3 | c.8657G>A p.R2886Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs759341431; called by muse, mutect2, varscan2
- STAG2 | c.1437C>G p.Y479* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54356277, COSV99493317; called by muse, mutect2, varscan2
- ATP2A2 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CACHD1 | c.1273G>T p.V425L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ETV6 | c.416_417del p.S139Yfs*14 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by pindel, varscan2
- SNX33 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CILP | c.3276C>T p.L1092= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs144863148; called by muse, mutect2, varscan2
- OGDHL | c.162G>A p.E54= | Silent (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
